Surgical pathology report (de-identified scan), TCGA case TCGA-JX-A3Q0, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Washington University, specimen TCGA-JX-A3Q0-01A (Primary Tumor).

Surgical Pathology Report

Final

Amended?

Surg Path #:

Pat Name:

DOB:

Sex:

Female

MRN #:

Service:

Location:

Hospital #:

Date Taken:

Date Rec'd:

Attend Phys:

Final Dx: "VAGINAL-CERVICAL BIOPSY", BIOPSY

- MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

BLADDER, BIOPSY

- MARKED CHRONIC INFLAMMATION REACTIVE EPITHELIAL ATYPIA

- NO CARCINOMA IDENTIFIED

Primary Path:

Resident Path:

Gross: The specimens are received in two formalin-filled containers, each labeled with the patient's name.

The first container, designated "bladder biopsy," holds six minute, pale white to glistening yellow tissue fragments. The largest fragment measures 0.7 x 0.1 x 0.1 cm. The tissue is entirely submitted in cassette A. Jar 0.

The second container, designated "vaginal-cervical biopsy," holds a 1.0 x 0.7 x 0.4 cm tan-brown tissue fragment with a roughened, friable surface. The tissue is bisected and entirely submitted in B. Jar 0.

Comment: Histologic sections from the vaginal-cervical biopsy show moderately differentiated squamous cell carcinoma. Histologic sections from the bladder biopsy show fragments of markedly inflamed transitional mucosa with reactive epithelial atypia. No squamous cell carcinoma is identified.

History: The patient is a year old female with squamous cell carcinoma (unknown primary).

Operative procedure: Examination under anesthesia/cystoscopy/bladder and cervical biopsies.

Date Last Men:

Mens. Status:

Contraceptive:

Other Horm:

Prev Atypical:

ICD-O-3

carcinoma, squamous cell, NOS 8070/3

Site: Cervix, NOS C53.9

2-28-12 RD

Source: NCI Genomic Data Commons file 421f9581-0cbd-42ab-838d-e9ce74e6668a (TCGA-JX-A3Q0.3CE379FF-5E2B-4DE5-BBD8-51D70E6EFF73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).